Somatic mutation profile of tumor specimen TCGA-60-2707-01A (aliquot TCGA-60-2707-01A-01W-0877-08) from TCGA case TCGA-60-2707, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.5 years (25,758 days).
Specimen TCGA-60-2707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0804694-0b20-47b2-a146-2b8a116aec79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2707-11A (Solid Tissue Normal), aliquot TCGA-60-2707-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f4779ce-14c5-45e1-8889-03aae89f7c45

The open-access MAF lists 93 somatic variants for this specimen: 70 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 21, Nonsense Mutation 5, Splice Site 3, Intron 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 19/30 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123316, CM110129, COSV64290165, COSV64300390, COSV64310812; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3633C>G p.N1211K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.674); catalogued as COSV55593882, COSV55602024; called by muse, mutect2, varscan2
- ADAMTS12 | c.3443C>T p.T1148I | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV61256251, COSV61263358; called by muse, mutect2, varscan2
- ADAMTS20 | c.3298G>A p.D1100N | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as rs779152806, COSV67140075; called by muse, mutect2, varscan2
- ADAMTS8 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57291496, COSV99961715; called by muse, mutect2, varscan2
- ALPK3 | c.4190G>A p.C1397Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as COSV51930230; called by muse, mutect2, varscan2
- ALPK3 | c.4469G>T p.R1490L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV51930249; called by muse, mutect2, varscan2
- AMPD3 | c.184G>T p.E62* (on ENST00000396553 / NM_001025389.2; = p.E71* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV67329986; called by muse, mutect2, varscan2
- ANKRD50 | c.2605C>A p.Q869K | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.18); catalogued as COSV72385092; called by muse, mutect2, varscan2
- ARMCX2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV57529345; called by muse, mutect2, varscan2
- BARX2 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV55649424; called by muse, mutect2, varscan2
- BMPER | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51811279; called by muse, mutect2, varscan2
- CCN6 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57888784; called by muse, mutect2, varscan2
- CDH13 | c.850T>C p.Y284H | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51871274; called by muse, mutect2, varscan2
- CHAT | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60320564; called by muse, mutect2, varscan2
- CLCA1 | c.2243C>A p.P748H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV52325409, COSV52331460; called by muse, mutect2, varscan2
- CPLANE1 | c.8230A>G p.I2744V | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV57053086; called by muse, mutect2, varscan2
- CRYBG1 | c.4709A>T p.H1570L | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV64814795; called by muse, mutect2, varscan2
- CSMD2 | c.2659G>T p.A887S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.556); catalogued as COSV53883241; called by muse, mutect2, varscan2
- CUBN | c.1572G>T p.M524I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV64708590; called by muse, mutect2, varscan2
- ERCC6 | c.2091A>T p.L697F | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63388050; called by muse, mutect2, varscan2
- F13B | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201195929, COSV66375813; called by muse, mutect2
- FGF10 | c.584A>T p.K195I | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV52940067; called by muse, mutect2
- GRID1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 8/266 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422356227, COSV60012681; called by muse, mutect2
- HBD | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV53082010; called by muse, mutect2, varscan2
- HSPA2 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55968865; called by muse, mutect2, varscan2
- KIF21A | c.945C>G p.S315R | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV62767633; called by muse, mutect2, varscan2
- LHX9 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61326934; called by muse, mutect2, varscan2
- LRIG1 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56237177; called by muse, mutect2, varscan2
- LRRK1 | c.3560A>T p.Y1187F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV52602882, COSV99438158; called by muse, mutect2, varscan2
- MMP16 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV54152271; called by mutect2, varscan2
- NECTIN4 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV63511980; called by muse, mutect2, varscan2
- NPTXR | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs887146414, COSV60727763; called by muse, mutect2, varscan2
- OR5K3 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 111/545 reads (20%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.981); catalogued as COSV67349714, COSV67349737, COSV67349776; called by muse, mutect2, varscan2
- OR5K3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 110/541 reads (20%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.461); catalogued as COSV67349600, COSV67349718; called by muse, mutect2, varscan2
- OR8G5 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.118); catalogued as COSV100422164; called by muse, mutect2
- PALM2AKAP2 | c.238G>T p.E80* (on ENST00000259318 / NM_001136562.3; = p.E311* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as COSV52173657; called by muse, mutect2, varscan2
- PAPPA2 | c.3151G>T p.V1051L | Missense Mutation (SNP) | VAF 167/417 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62791320; called by muse, mutect2, varscan2
- PCNX2 | c.3459G>A p.W1153* | Nonsense Mutation (SNP) | VAF 35/119 reads (29%) | catalogued as COSV50906588; called by muse, mutect2, varscan2
- PCNX2 | c.3458G>T p.W1153L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50907055; called by muse, mutect2, varscan2
- PIK3C2B | c.3623A>G p.H1208R | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV65809299; called by muse, mutect2, varscan2
- PMFBP1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV52832568; called by muse, varscan2
- RFTN2 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54386085; called by muse, mutect2, varscan2
- RHBDL3 | c.668+1G>C p.X223_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52184694; called by muse, mutect2, varscan2
- RLF | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV65653409; called by mutect2, varscan2
- RNF19A | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV61994929; called by muse, mutect2
- RYR3 | c.2813C>A p.A938D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV66809444; called by muse, mutect2, varscan2
- SAMD9L | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 22/652 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs1427801576, COSV59085584; called by muse, mutect2
- SDR42E1 | c.694C>G p.H232D | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61093783; called by muse, mutect2, varscan2
- SLC26A7 | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 118/335 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52586912; called by muse, mutect2, varscan2
- SLC39A12 | c.676A>G p.N226D | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101070170, COSV66195404; called by muse, mutect2, varscan2
- SLC6A11 | c.392-1G>T p.X131_splice | Splice Site (SNP) | VAF 25/82 reads (30%) | catalogued as COSV54390155; called by muse, mutect2, varscan2
- SLC6A11 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54390164; called by muse, mutect2, varscan2
- SMG1 | c.3856C>G p.Q1286E | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.206); catalogued as COSV67174955; called by muse, mutect2, varscan2
- SPTA1 | c.5657T>C p.L1886P | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63749352; called by muse, mutect2, varscan2
- TBC1D21 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 87/294 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV55994597, COSV55994712; called by muse, mutect2, varscan2
- TBC1D9 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs900762462; called by muse, mutect2, varscan2
- TNFSF4 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs1394319992; called by muse, mutect2, varscan2
- TP53 | c.102del p.L35Cfs*9 | Frame Shift Del (DEL) | VAF 209/577 reads (36%) | catalogued as COSV52833841; called by mutect2, pindel, varscan2
- TPR | c.2363A>T p.K788M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV66599594; called by muse, mutect2, varscan2
- VRK2 | c.857-2A>T p.X286_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV60874847; called by muse, mutect2, varscan2
- VWA3B | c.2635G>T p.V879F | Missense Mutation (SNP) | VAF 100/423 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs370362777, COSV68241082; called by muse, mutect2, varscan2
- CACNG2 | c.53T>C p.F18S | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- FAM83H | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IGKV6D-21 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDM1 | c.1818C>G p.H606Q | Missense Mutation (SNP) | VAF 8/288 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.036); called by muse, mutect2
- OOEP | c.351C>A p.H117Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- PI4KA | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- UCMA | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 23/215 reads (11%) | called by muse, mutect2, varscan2
- ZSWIM3 | c.1616C>G p.S539C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACSM5 | c.1056T>C p.P352= | Silent (SNP) | VAF 81/272 reads (30%) | catalogued as COSV59369700; called by muse, mutect2, varscan2
- ADCY8 | c.2514C>T p.F838= | Silent (SNP) | VAF 46/264 reads (17%) | called by muse, varscan2
- ARSG | c.819C>T p.L273= | Silent (SNP) | VAF 38/360 reads (11%) | catalogued as COSV71594023; called by muse, mutect2, varscan2
- ASMT | c.318G>A p.L106= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as rs370304793; called by muse, varscan2
- GALC | c.1221A>G p.Q407= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs747714175, COSV54323263; called by muse, mutect2, varscan2
- GATA1 | c.1131C>T p.S377= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV64961542; called by muse, mutect2, varscan2
- GCSAML | c.19C>A p.R7= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV63577121, COSV63577142; called by muse, mutect2, varscan2
- GRSF1 | c.753G>A p.V251= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV54657328; called by muse, mutect2, varscan2
- HERC2 | c.846C>A p.P282= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV55309190; called by muse, varscan2
- IGSF1 | c.483C>T p.F161= | Silent (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- MED12L | c.2220A>G p.A740= | Silent (SNP) | VAF 147/629 reads (23%) | catalogued as COSV56369542; called by muse, mutect2, varscan2
- MTOR | c.3987G>C p.L1329= | Silent (SNP) | VAF 51/169 reads (30%) | catalogued as COSV63868732; called by muse, varscan2
- OR10AG1 | c.579A>T p.V193= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV56631630; called by muse, mutect2, varscan2
- RC3H2 | c.1563G>A p.V521= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- SLC35F5 | c.1122A>G p.L374= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs752592823, COSV55517012; called by muse, mutect2, varscan2
- SORBS2 | c.1788C>T p.S596= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs1223387064, COSV52992070; called by muse, mutect2, varscan2
- ST8SIA6 | c.222G>T p.S74= | Silent (SNP) | VAF 102/443 reads (23%) | catalogued as COSV66461131; called by muse, mutect2, varscan2
- SYNE1 | c.2577A>G p.L859= (on ENST00000367255 / NM_182961.4; = p.L866= on NM_033071.3) | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV55111555; called by muse, mutect2, varscan2
- TMLHE | c.117C>G p.V39= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as COSV57689701; called by muse, mutect2, varscan2
- TP63 | c.1878C>T p.V626= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- UBC | c.355T>C p.L119= | Silent (SNP) | VAF 117/219 reads (53%) | catalogued as rs774168460, COSV100298830; called by muse, mutect2
- NCL | c.898+47G>A | Intron (SNP) | VAF 51/171 reads (30%) | catalogued as COSV59544954; called by muse, mutect2, varscan2
- PDHA2 | c.*2G>T | 3'UTR (SNP) | VAF 37/150 reads (25%) | catalogued as COSV54777404; called by muse, mutect2, varscan2
